FM case AD8399 — Foundation Medicine Adult Cancer Clinical Dataset (FM-AD)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Squamous Cell Neoplasms.
https://portal.gdc.cancer.gov/cases/f2452d03-f240-4e2d-a1bc-79bfbc53d1c8

Male, 74.1 years: Squamous cell carcinoma, NOS (ICD-O-3 8070/3); metastasis biopsied or resected from the eye. Tumor nuclei on the sequenced sample's slide: 20% (pathologist estimate recorded by GDC). Sample type: Metastatic.
